Somatic mutation profile of tumor specimen MMRF_2560_1_BM_CD138pos (aliquot MMRF_2560_1_BM_CD138pos_T1_KHS5U_K15133) from MMRF case MMRF_2560, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,090 days).
Specimen MMRF_2560_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aad8f0e-580f-4a74-8d8c-14c556c8b4da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2560_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2560_1_PB_Whole_C3_KHS5U_K15132; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff901697-bdfd-4f06-825b-bef3b879876a

The open-access MAF lists 97 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 22, Intron 12, Silent 11, 5'Flank 7, RNA 4, 5'UTR 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.1156C>A p.R386S | Missense Mutation (SNP) | VAF 107/194 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs199509734; called by muse, mutect2, varscan2
- CLASRP | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs770927672; called by muse, varscan2
- COL22A1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225221507, COSV57336822; called by muse, mutect2, varscan2
- CPNE2 | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV51960678; called by muse, mutect2, varscan2
- CXCR2 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 118/245 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs186640530, COSV59279930; called by muse, mutect2, varscan2
- DNAH10 | c.4862C>T p.S1621L (on ENST00000409039; = p.S1560L on NM_207437.3) | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1387399038, COSV68989863; called by muse, mutect2, varscan2
- GJA3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 109/198 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs375041482, COSV53834889; called by muse, mutect2, varscan2
- ICAM1 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780437504, COSV53423857; called by muse, mutect2, varscan2
- IGLV3-1 | c.226A>C p.I76L | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs374050608; called by muse, mutect2, varscan2
- IGLV4-60 | c.227G>C p.S76T | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs369368652; called by muse, mutect2, varscan2
- KIFC3 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1555607863, COSV65550924; called by muse, mutect2, varscan2
- KNL1 | c.6234G>A p.M2078I (on ENST00000346991 / NM_170589.5; = p.M2052I on NM_144508.5) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV61158323; called by muse, mutect2, varscan2
- MAP2K3 | c.877C>A p.R293S (on ENST00000342679 / NM_145109.3; = p.R264S on NM_002756.4) | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.386); catalogued as rs777252658, COSV100384185; called by muse, mutect2, varscan2
- MINAR2 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1251372086, COSV57993695; called by muse, mutect2, varscan2
- NLRP5 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs778328871, COSV66764528; called by muse, mutect2, varscan2
- PNPLA5 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs1179227091, COSV53374281; called by muse, mutect2, varscan2
- PPFIA1 | c.3311C>T p.T1104I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.304); catalogued as rs1365124636, COSV54137365; called by muse, mutect2, varscan2
- PPM1N | c.962G>A p.C321Y | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1389492140; called by muse, mutect2, varscan2
- SEC14L4 | c.774C>T p.I258= | Splice Region (SNP) | VAF 21/57 reads (37%) | catalogued as rs1378125278; called by muse, mutect2, varscan2
- ALDH16A1 | c.2363T>A p.L788Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ANKRD27 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 101/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AUTS2 | c.3550C>A p.L1184I | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2
- CCDC138 | c.890A>T p.D297V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DLG2 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DNAH11 | c.4875T>A p.F1625L | Missense Mutation (SNP) | VAF 125/269 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- EMD | c.216T>A p.D72E | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GFPT2 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IMPG1 | c.1036C>G p.P346A | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KAT8 | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LRRC24 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13C4 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 82/377 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PRDM9 | c.351G>A p.K117= | Splice Region (SNP) | VAF 98/343 reads (29%) | called by muse, mutect2, varscan2
- PTPRS | c.3020A>C p.D1007A | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RAD51AP2 | c.1036A>T p.I346F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- SPESP1 | c.962C>G p.P321R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1721T>C p.V574A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF595 | c.1445G>T p.C482F | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF880 | c.656A>T p.K219M | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CLUH | c.3468C>T p.Y1156= (on ENST00000435359; = p.Y1195= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs1191262302; called by muse, mutect2, varscan2
- CXXC4 | c.582T>C p.N194= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- LRP3 | c.1407C>T p.F469= | Silent (SNP) | VAF 87/248 reads (35%) | catalogued as rs763848751, COSV53503951; called by muse, mutect2, varscan2
- RYR2 | c.7086C>G p.P2362= | Silent (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- SLC6A6 | c.936G>T p.L312= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- SOS1 | c.3276T>G p.A1092= | Silent (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- SRCIN1 | c.3039G>A p.T1013= (on ENST00000621492; = p.T979= on NM_025248.3) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs376616774; called by muse, mutect2, varscan2
- SYVN1 | c.1005T>C p.R335= | Silent (SNP) | VAF 44/210 reads (21%) | called by muse, mutect2, varscan2
- TRIO | c.7917G>A p.R2639= | Silent (SNP) | VAF 86/310 reads (28%) | called by muse, mutect2, varscan2
- VPS8 | c.1917G>A p.L639= (on ENST00000625842 / NM_001349294.1; = p.L637= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- ZFP42 | c.486A>G p.L162= | Silent (SNP) | VAF 120/188 reads (64%) | called by muse, mutect2, varscan2
- ACHE | chr7:100896743 C>T | 5'Flank (SNP) | VAF 85/177 reads (48%) | called by muse, mutect2, varscan2
- ACTN2 | c.*227G>T | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.2575+34C>T | Intron (SNP) | VAF 76/186 reads (41%) | called by muse, mutect2, varscan2
- ANKRD26 | c.*219C>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- ANKRD30A | chr10:37125759 C>T | 5'Flank (SNP) | VAF 3/28 reads (11%) | catalogued as rs1220868125; called by muse, mutect2
- ASB7 | c.-27C>T | 5'UTR (SNP) | VAF 224/406 reads (55%) | catalogued as rs764077861; called by muse, mutect2, varscan2
- C8orf86 | n.901G>A | RNA (SNP) | VAF 47/115 reads (41%) | called by muse, mutect2, varscan2
- CCDC171 | c.3600+8451A>G | Intron (SNP) | VAF 13/59 reads (22%) | catalogued as rs1401199382; called by muse, mutect2, varscan2
- CCM2 | c.-8G>A | 5'UTR (SNP) | VAF 7/9 reads (78%) | catalogued as rs1476414898; called by muse, mutect2, varscan2
- CCNT1 | c.*870C>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- CDH11 | c.-148C>T | 5'UTR (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- CSMD3 | c.*438A>G | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- DCP1B | chr12:2004513 C>A | 5'Flank (SNP) | VAF 66/73 reads (90%) | called by muse, mutect2, varscan2
- DDX47 | c.371-17T>C | Intron (SNP) | VAF 27/28 reads (96%) | called by muse, mutect2, varscan2
- ELFN2 | c.*2423G>A | 3'UTR (SNP) | VAF 64/132 reads (48%) | called by muse, mutect2, varscan2
- FAM8A1 | c.*375G>A | 3'UTR (SNP) | VAF 3/11 reads (27%) | catalogued as rs200864954; called by muse, mutect2
- HAP1 | c.*1619C>T | 3'UTR (SNP) | VAF 95/179 reads (53%) | catalogued as rs1555587469, COSV57881433; called by muse, mutect2, varscan2
- HFE | c.*2882A>C | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- HSPB7 | chr1:16019208 G>T | 5'Flank (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- HYDIN2 | n.9401G>A | RNA (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.64T>C | RNA (SNP) | VAF 91/194 reads (47%) | catalogued as rs1421221921; called by muse, mutect2, varscan2
- KCTD2 | c.*43C>T | 3'UTR (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+6047C>T | Intron (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- KIF5A | chr12:57546188 G>T | 5'Flank (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- LAIR1 | c.*8C>G | 3'UTR (SNP) | VAF 164/277 reads (59%) | catalogued as rs754763759; called by muse, mutect2, varscan2
- LIMA1 | c.865-227G>A | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- MIR1208 | n.69G>A | RNA (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- MRPS6 | c.46-120A>C | Intron (SNP) | VAF 9/12 reads (75%) | called by muse, mutect2
- NPR3 | c.*3731T>C | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- NPTXR | c.*1158G>A | 3'UTR (SNP) | VAF 80/179 reads (45%) | catalogued as rs529948550; called by muse, mutect2, varscan2
- OAS2 | c.448+1148A>T | Intron (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- PCDH11Y | c.*4080T>C | 3'UTR (SNP) | VAF 87/100 reads (87%) | called by muse, mutect2, varscan2
- PGR | c.2646+25T>C | Intron (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- PPM1A | c.-20-5625T>G | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- PROB1 | c.*10C>T | 3'UTR (SNP) | VAF 37/109 reads (34%) | catalogued as rs767366714; called by muse, mutect2, varscan2
- PURG | c.*656T>C | 3'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- RPL7 | chr8:73293981 C>A | 5'Flank (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2
- RWDD1 | c.*3976A>G | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- SCARB1 | c.1651+42T>G | Intron (SNP) | VAF 79/194 reads (41%) | called by muse, mutect2, varscan2
- SKP2 | chr5:36152031 G>A | 5'Flank (SNP) | VAF 100/307 reads (33%) | catalogued as rs1040998078; called by muse, mutect2, varscan2
- STK39 | c.*639A>C | 3'UTR (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- SYT4 | c.*535T>G | 3'UTR (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- TES | c.1077+262dup | Intron (INS) | VAF 30/80 reads (38%) | called by mutect2, varscan2
- TUBB6 | c.278-80C>T | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- UNC5C | c.*2597G>T | 3'UTR (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- ZADH2 | c.*3105T>C | 3'UTR (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- ZFP37 | c.*1938dup | 3'UTR (INS) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- ZNF25 | c.*1992T>A | 3'UTR (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
